Surgical pathology report (de-identified scan), TCGA case TCGA-23-1021, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-1021-01B (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

PATIENT:

Hospital No.:

Date of Birth:

Rec:

Col:

Location:

Pathologist:

Assistant:

Attending MD:

Ordering MD:

Copies To:

=====

DIAGNOSIS:

1. OMENTUM #1, PARTIAL OMENTECTOMY:

- Metastatic high-grade serous adenocarcinoma with psammomatous calcification

2,5. RIGHT AND LEFT ADNEXA, BILATERAL SALPINGO-OOPHORECTOMY:

- Poorly-differentiated papillary serous adenocarcinoma involving right and left ovaries, see Comment
- Grade III
- The tumor is bilateral
- Diameter of tumor: right ovary 9.5 x 6.5 x 5.5 cm
left ovary: 8.0 x 6.0 x 4.3 cm
- Tumor involves bilateral ovarian surfaces
- Foci of lymphovascular space invasion present
- Moderate necrosis present
- Stage: FIGO IIIC pT3c Nx Mx
- Focal residual left ovary shows luteinized follicle cyst
- No recognizable right ovary identified
- The bilateral ovarian surfaces also show associated adhesions with reactive mesothelial hyperplasia
- Right fallopian tube:
- Poorly-differentiated papillary serous adenocarcinoma
- Grade III
- Carcinoma shows transmural extension including serosal involvement
- Associated serosal adhesions with reactive mesothelial hyperplasia
- Mesosalpinx shows involvement by carcinoma
- Focal mesonephric duct remnants present
- Left fallopian tube:
- Metastatic carcinoma involving serosa and mesosalpinx with associated reactive mesothelial hyperplasia and surface adhesion
- Intraluminal detached tufts of malignant cells present

3. UTERUS AND CERVIX, TOTAL ABDOMINAL HYSTERECTOMY:

- Serosal involvement by metastatic high-grade serous carcinoma

(continued on next page)□

Page: 2

with subserosal extension and extensive tumor emboli in vascular spaces within the myometrium

- Inactive endometrium
- Acute and chronic cervicitis with squamous metaplasia
- Leiomyoma with foci of mild edema (11.0 x 10.0 x 7.0 cm, intramural)
- Serosal adhesions with reactive mesothelial hyperplasia and acute and chronic inflammation

[page 2 of 4]
4. CUL DE SAC, TUMOR, EXCISION:
- Metastatic high-grade serous adenocarcinoma
- Two serous epithelial-lined cyst showing surface involvement by carcinoma
6. RECTOSIGMOID TUMOR, EXCISION:
- Metastatic high-grade serous adenocarcinoma
- Associated adhesions and reactive mesothelial hyperplasia

COMMENT: Primary bilateral ovarian serous adenocarcinoma is favored, the alternate possibility of a primary right fallopian tube serous adenocarcinoma is also considered.

Case discussed with

=====

HISTORY: Pelvic mass/ascites

MICROSCOPIC:

See Diagnosis.

GROSS:

1: OMENTUM NO 1

Labeled with the patient's name, labeled "omentum", received fresh in the O.R. for frozen section diagnosis, and subsequently fixed in formalin are multiple irregular unoriented rubbery to firm tan-yellow focally hemorrhagic portions of omentum weighing 350 grams and measuring 16.0 x 12.0 x 4.0 cm in aggregate dimensions. Serial sectioning reveals a rubbery to firm cut surface consisting of tan-yellow focally necrotic adipose tissue interspersed with firm pink-white tissue, largest measuring 2.5 cm in greatest dimension. Representative sections.

A. Frozen section remnant #1 - 1

B-D. 2 each

2: RIGHT ADNEXA

Labeled with the patient's name, labeled "right adnexa", received fresh in the O.R. for frozen section diagnosis, and subsequently fixed in formalin is a rubbery tan-pink focally hemorrhagic ovarian mass with an attached fimbriated fallopian tube weighing 220 grams. The ovary measures 9.5 x 6.5 x 5.5 cm in greatest dimension. The external surface of the ovary shows focal hemorrhage, adhesions and papillary tan-pink tissue. Serial sectioning of the ovary reveals solid tan-pink papillary tissue interspersed with cyst spaces filled with serous fluid. The cyst spaces measure up to 5.0 cm. The attached fallopian tube is fimbriated and measures 6.5 cm in length and up to 1.2 cm in diameter. The serosa is tan-pink focally hemorrhagic. Sectioning of the distal half of the tube reveals firm

(continued on next page)□

cont.

Page: 3

tan-white tumor measuring 1.7 x 1.1 x 1.1 cm No normal ovarian parenchyma is grossly identified. Representative sections.

E. Frozen section remnant #2 - 2

F. Proximal fallopian tube - 2

G. Distal fallopian tube including firm tan tissue - 3

H-K. Ovary - 1 each

BB. Tumor on external surface -2

3: UTERUS AND CERVIX

Labeled with the patient's name, labeled "uterus", received fresh in the O.R. for frozen section diagnosis, and subsequently fixed in formalin is a uterus with attached cervix weighing 1170 grams and measuring 20.0 cm from fundus to ectocervix, 11.0 cm from right to left, and 11.5 cm from anterior to posterior, in greatest dimensions. The serosa is tan-red focally hemorrhagic shows multiple adhesions and nodules of rubbery to firm tan focally hemorrhagic tissue. The

[page 3 of 4]
cervix measures 3.5 cm in length and up to 3.0 cm in external diameter. The ectocervical mucosa is smooth and tan-pink and contains a central ovoid os which measures 0.8 cm in width. The transformation zone is distinct. The endocervical canal is soft tan and rugose. No cervical polyps or masses are identified. The endometrial cavity is compressed and measures 5.5 cm in length and up to 3.0 cm in width and is lined by a soft tan endometrium which measures up to 0.1 cm in thickness. No endometrial polyps or masses are identified. The myometrium is pink-tan, shows some trabeculations, and measures up to 9.0 cm in thickness. The myometrium contains a large rubbery tan focally cystic and focally hemorrhagic intramural fundal mass which measures 11.0 x 10.0 x 7.0 cm. On sectioning, the cyst-like spaces are filled with a gelatinous tan material. Representative sections.

- L. Frozen section remnant #3 - 2
- M. Anterior cervix - 1
- N. Posterior cervix - 1
- O. Serosal nodules - 4
- P. Anterior corpus - 1
- Q. Posterior corpus - 1
- R,S. Fundal mass - 2 each

4: CUL DE SAC TUMOR

Labeled "cul de sac tumor" and received in formalin is a 4 x 1.3 x 1 cm piece of tan-white soft tissue with two attached cysts measuring 0.5 cm in diameter and 1.4 x 1.4 x 1 cm respectively. The cysts are filled with serous fluid and their walls measure less than 0.1 cm in thickness. Representative sections.

- T. 3

5: LEFT ADNEXA

Labeled "left adnexa" and received in formalin is a 170 gram specimen measuring 9 x 8 x 4.5 cm. The ovary measures 8 x 6 x 4.3 cm and is replaced by a cystic and solid tumor. No normal ovarian tissue is identified. The tumor invades the capsule externally. The cysts are filled with serous fluid. The solid areas of the ovarian tumor are soft, white, transparent. The fallopian tube measures 6 cm length and 0.8 to 1 cm in diameter and seems unaffected by tumor. The soft tissue surrounding the ovary and fallopian tube is hemorrhagic.

(continued on next page)□

cont.

Page: 4

Representative sections.

- U. Cyst - 2
- V,W. Solid areas of tumor - 1 each
- X. Cyst and surrounding hemorrhage
- Y. Fallopian tube - 2
- Z. Tumor outside ovarian capsule - 2
- CC. Tumor on external surface -2

6: RECTO SIGMOID TUMOR

Labeled "rectosigmoid tumor" and received in formalin are seven pieces of a friable white-tan soft tissue that range from 0.5 to 2 cm in largest dimension. On sectioning the specimen shows papillae and cystic areas. Representative sections.

- AA. 2

Gross dictated by .

OPERATIVE CALL

[page 4 of 4]
OPERATIVE CONSULT (FROZEN #1):

OMENTUM, PARTIAL OMENTECTOMY:

- Metastatic Mullerian-derived carcinoma with papillary, glandular and solid growth patterns and associated calcifications, including psammoma bodies

OPERATIVE CALL

OPERATIVE CONSULT (FROZEN #2):

RIGHT FALLOPIAN TUBE AND OVARY, SALPINGO-OOPHORECTOMY:

- Mullerian-derived adenocarcinoma with at least some serous features and associated psammoma bodies involving ovary and fallopian tube

OPERATIVE CONSULT (FROZEN #3):

UTERUS, HYSTERECTOMY (SELECTED SECTION OF UTERINE CORPUS):

- Metastatic carcinoma with serous features and psammoma bodies on serosal surface and involving subserosal (PAUSE IN DICTATION). A portion of the omental tumor is submitted for clonogenic assay. Portions of omental tumor and tumor from right ovary and tube released to lab

Special Studies: Frozen section

See Also:

DATE:

Pathologist

I, _____ the pathologist of record, have personally examined the specimen, interpreted the results, reviewed this report and signed it electronically.

Date Finalled:

Source: NCI Genomic Data Commons file 79612c4f-7ad2-4c23-90c6-348b7e8a7eb7 (TCGA-23-1021.4339A934-71A0-4E92-91D6-BEB0207939ED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).